Somatic mutation profile of tumor specimen TARGET-10-PARBTA-09A (aliquot TARGET-10-PARBTA-09A-01D) from TARGET case TARGET-10-PARBTA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,654 days).
Specimen TARGET-10-PARBTA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9893fb6-335b-4ed2-a6ac-bdffc119df74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBTA-10A (Blood Derived Normal), aliquot TARGET-10-PARBTA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/709dba23-2e62-4b42-a7a3-29a8d6d176bb

The open-access MAF lists 79 somatic variants for this specimen: 33 protein-altering or splice-affecting, 23 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 23, Intron 8, RNA 6, 3'UTR 6, Nonsense Mutation 2, 5'UTR 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 39/93 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- CCN6 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs991418553; called by muse, mutect2, varscan2
- COL4A3 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0.047); catalogued as COSV67416413; called by muse, mutect2, varscan2
- COL6A3 | c.2815G>A p.G939R | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1207431896; called by muse, mutect2, varscan2
- DSCAM | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.88); catalogued as rs752670424, COSV68022860; called by muse, mutect2, varscan2
- FCGBP | c.11617C>T p.R3873C | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs758242820; called by muse, mutect2, varscan2
- FRYL | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977300; called by muse, mutect2, varscan2
- GABRA3 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765716874; called by muse, varscan2
- GABRB1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54972822; called by muse, mutect2, varscan2
- KCNK2 | c.335C>T p.T112M (on ENST00000444842 / NM_001017425.3; = p.T97M on NM_014217.4) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.335); catalogued as rs1245684698, COSV67208269; called by muse, mutect2, varscan2
- KMT2A | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63293510; called by muse, mutect2, varscan2
- MROH7 | c.3289C>T p.R1097* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs764872939; called by muse, mutect2
- NDST4 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.37); catalogued as COSV99996669; called by muse, mutect2, varscan2
- NOTCH3 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475080033, CM003015; called by muse, mutect2, varscan2
- NYNRIN | c.3277G>A p.A1093T | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as rs777933278, COSV66841162; called by muse, mutect2, varscan2
- SMO | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs772693769, COSV50824406; called by muse, mutect2, varscan2
- TIGD4 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs552065116; called by muse, mutect2, varscan2
- TMPRSS9 | c.1995G>A p.W665* (on ENST00000648592; = p.W631* on NM_182973.2) | Nonsense Mutation (SNP) | VAF 27/48 reads (56%) | catalogued as COSV100211177; called by muse, mutect2, varscan2
- TRRAP | c.5293G>A p.G1765R (on ENST00000359863 / NM_001244580.1; = p.G1747R on NM_003496.3) | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs145834316; called by muse, mutect2, varscan2
- ZFHX4 | c.9073C>T p.H3025Y | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50480992; called by muse, mutect2, varscan2
- ACACB | c.5630C>T p.S1877F | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ADARB1 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL19A1 | c.515A>C p.H172P | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH14 | c.5362G>A p.E1788K (on ENST00000445597; = p.E2193K on NM_001367479.1) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KRTAP1-4 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.32); called by muse, mutect2, varscan2
- NECTIN3 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- OR4C46 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB7 | c.2221G>A p.G741R | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2
- PJVK | c.275_276insGACCCCCCAAGCCCGAG p.G93Tfs*11 | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- RGMA | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TBC1D8 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- UNC13C | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZNF233 | c.672T>A p.D224E | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ALDH1L1 | c.1728C>T p.P576= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs766927576; called by muse, mutect2, varscan2
- ANKRD30A | c.1119G>A p.T373= (on ENST00000611781; = p.T317= on NM_052997.2) | Silent (SNP) | VAF 90/301 reads (30%) | catalogued as rs768361506, COSV64614767, COSV64615588; called by muse, mutect2, varscan2
- COL4A4 | c.4032G>A p.E1344= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- EFCAB8 | c.3177G>A p.K1059= | Silent (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- FAT1 | c.9357C>T p.N3119= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs529893591; called by muse, mutect2
- GLP1R | c.1233G>A p.L411= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs1298807315; called by muse, mutect2, varscan2
- GPS1 | c.1245C>T p.A415= | Silent (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- GRM8 | c.1587G>A p.V529= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs1384113261, COSV100281626; called by muse, mutect2, varscan2
- INPP5K | c.1020C>T p.T340= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as rs141224887; called by muse, mutect2, varscan2
- IRX2 | c.429C>T p.T143= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- ITM2A | c.474G>A p.G158= | Silent (SNP) | VAF 55/107 reads (51%) | catalogued as COSV64810877; called by muse, mutect2, varscan2
- KIF21A | c.1665G>A p.K555= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs1387768252, COSV100735173; called by muse, varscan2
- KRT13 | c.141C>T p.G47= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs374219463; called by muse, mutect2, varscan2
- LAMA3 | c.8442G>A p.R2814= (on ENST00000313654 / NM_198129.4; = p.R1205= on NM_000227.6) | Silent (SNP) | VAF 58/200 reads (29%) | called by muse, mutect2, varscan2
- MAGEB18 | c.1031G>A p.*344= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV57464490; called by muse, mutect2, varscan2
- OSBPL9 | c.501A>T p.V167= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, varscan2
- PCDH15 | c.4911G>A p.E1637= | Silent (SNP) | VAF 72/196 reads (37%) | catalogued as rs972342055, COSV100220613; called by muse, mutect2, varscan2
- PRKD1 | c.1476C>T p.F492= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as rs1050229277, COSV59558823; called by muse, mutect2, varscan2
- SEL1L3 | c.922C>T p.L308= | Silent (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- TF | c.957C>T p.H319= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs565363550, COSV99396384; called by muse, mutect2, varscan2
- TLR4 | c.2332C>T p.L778= (on ENST00000355622 / NM_138554.5; = p.L738= on NM_003266.4) | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs199519992; called by muse, varscan2
- TNPO2 | c.150C>T p.F50= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs201975298, COSV63509525; called by muse, mutect2, varscan2
- TRPM3 | c.2718G>A p.Q906= (on ENST00000357533 / NM_001366142.2; = p.Q749= on NM_020952.6) | Silent (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- ABCC13 | n.253G>A | RNA (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- ADAM21P1 | n.170C>T | RNA (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2
- ANOS1 | c.*7C>T | 3'UTR (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- BDKRB2 | c.74+662G>A | Intron (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- CPA4 | c.703-51G>A | Intron (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- CYP2G1P | n.469C>T | RNA (SNP) | VAF 11/42 reads (26%) | catalogued as rs1018753785; called by muse, mutect2, varscan2
- DBF4B | c.1189+987C>T | Intron (SNP) | VAF 16/46 reads (35%) | catalogued as rs1242432558; called by muse, mutect2
- DPP3 | c.-54G>A | 5'UTR (SNP) | VAF 11/29 reads (38%) | catalogued as rs770608800; called by muse, mutect2, varscan2
- DST | c.*23C>T | 3'UTR (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- DST | c.21727+31G>A | Intron (SNP) | VAF 49/134 reads (37%) | called by muse, mutect2, varscan2
- EHD4 | c.*31G>A | 3'UTR (SNP) | VAF 8/19 reads (42%) | catalogued as rs1295008398; called by muse, mutect2, varscan2
- GDA | c.*2568C>T | 3'UTR (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87702526 C>A | 3'Flank (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- LINC00452 | n.612-3591G>A | Intron (SNP) | VAF 30/33 reads (91%) | called by muse, mutect2, varscan2
- LRATD1 | n.678C>T | RNA (SNP) | VAF 33/60 reads (55%) | called by muse, mutect2, varscan2
- LRRTM3 | c.-409G>A | 5'UTR (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- MIR1269A | n.3G>A | RNA (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- MIR487B | n.35C>T | RNA (SNP) | VAF 13/46 reads (28%) | catalogued as rs754567780; called by muse, mutect2, varscan2
- PRTFDC1 | c.*58G>A | 3'UTR (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2, varscan2
- SCN9A | c.902-63C>T | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2
- SLCO6A1 | c.1815-27G>A | Intron (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- TFAP2A | c.538+99C>T | Intron (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- THNSL2 | c.*102C>T | 3'UTR (SNP) | VAF 4/14 reads (29%) | catalogued as rs747665892, COSV100147255; called by muse, mutect2
